FM case AD64 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5e9ee7d5-f33a-46c4-a308-713814037dc6

Female, 37.7 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
